Somatic mutation profile of tumor specimen 0DVSBX from CCDI case PBCNBR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,806 days).
Specimen 0DVSBX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d846d980-1a3f-49f9-a714-50aa61d1b1a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVSCA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/610dab38-decc-4102-be34-d78e955e462c

The open-access MAF lists 46 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 12, Intron 4, Nonsense Mutation 3, 5'UTR 2, 3'UTR 2, 5'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 79/270 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 357/413 reads (86%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL1 | c.3700C>T p.R1234W (on ENST00000340736 / NM_001008701.3; = p.R1229W on NM_014921.5) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473367817; called by muse, mutect2
- CCL28 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.244); catalogued as rs1443999937; called by muse, mutect2, varscan2
- DDX43 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 53/410 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV64837834; called by muse, mutect2, varscan2
- ELMO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 395/695 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1447676557, COSV60297074; called by muse, mutect2, varscan2
- GRIP2 | c.3139C>T p.R1047W (on ENST00000619221; = p.R950W on NM_001080423.4) | Missense Mutation (SNP) | VAF 30/435 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as rs1489641967, COSV56123241; called by muse, mutect2
- MUTYH | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs373766973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10C1 | c.443C>T p.S148L (on ENST00000622521; = p.S146L on NM_013941.3) | Missense Mutation (SNP) | VAF 420/560 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV65822370; called by muse, mutect2, varscan2
- PDGFRA | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 2448/3104 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- RGPD3 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 69/262 reads (26%) | catalogued as rs780182038, COSV58739342; called by muse, mutect2, varscan2
- SCN9A | c.3069G>T p.E1023D (on ENST00000303354; = p.E1012D on NM_002977.3) | Missense Mutation (SNP) | VAF 174/408 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV57603549; called by mutect2, varscan2
- SLC16A5 | c.1152C>T p.A384= | Splice Region (SNP) | VAF 181/362 reads (50%) | catalogued as rs371576068, COSV100317326; called by muse, mutect2, varscan2
- TAS2R40 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 92/807 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs199829808; called by muse, mutect2, varscan2
- TEKT1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145821216; called by muse, mutect2, varscan2
- ASH1L | c.6496A>T p.K2166* (on ENST00000368346 / NM_001366177.2; = p.K2161* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 118/456 reads (26%) | called by muse, mutect2, varscan2
- CBLIF | c.838T>A p.Y280N | Missense Mutation (SNP) | VAF 153/393 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP63 | c.1275T>G p.H425Q | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CFTR | c.4346T>A p.L1449H | Missense Mutation (SNP) | VAF 199/633 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- COL8A1 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 44/471 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- COPB2 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.4); called by muse, mutect2
- DNAH14 | c.9566T>A p.I3189N (on ENST00000445597; = p.I4197N on NM_001367479.1) | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OTOGL | c.3637C>G p.L1213V (on ENST00000547103; = p.L1204V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PIEZO2 | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 155/389 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SEL1L2 | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 86/198 reads (43%) | called by muse, mutect2, varscan2
- AMER3 | c.1950C>A p.V650= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as COSV58467970; called by muse, mutect2
- CCDC77 | c.384C>T p.L128= | Silent (SNP) | VAF 122/268 reads (46%) | called by muse, varscan2
- CDC42BPG | c.948G>A p.L316= | Silent (SNP) | VAF 85/254 reads (33%) | catalogued as rs777874987; called by muse, mutect2, varscan2
- CRLF1 | c.276C>T p.N92= | Silent (SNP) | VAF 188/289 reads (65%) | catalogued as rs775994224, COSV66505392, COSV66505845; called by muse, mutect2, varscan2
- DLEU7 | c.411G>A p.T137= | Silent (SNP) | VAF 97/182 reads (53%) | catalogued as rs373725579; called by muse, mutect2, varscan2
- GAD1 | c.1518C>T p.G506= | Silent (SNP) | VAF 144/295 reads (49%) | catalogued as rs200287610, COSV64024954; called by muse, mutect2, varscan2
- HOXD11 | c.288C>T p.G96= | Silent (SNP) | VAF 55/95 reads (58%) | catalogued as rs1273334315; called by muse, mutect2, varscan2
- KDELR3 | c.132C>T p.F44= | Silent (SNP) | VAF 109/400 reads (27%) | called by muse, mutect2, varscan2
- MMRN2 | c.1968C>T p.D656= | Silent (SNP) | VAF 122/160 reads (76%) | catalogued as rs776837048; called by muse, mutect2, varscan2
- SERPINB12 | c.834T>C p.Y278= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- TMEM151B | c.897G>A p.S299= | Silent (SNP) | VAF 39/408 reads (10%) | catalogued as rs750035513; called by muse, mutect2
- TNFRSF25 | c.1032G>A p.A344= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as COSV61067983; called by muse, mutect2
- AP3B2 | c.1056-89C>T | Intron (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- CENPU | c.-14C>T | 5'UTR (SNP) | VAF 32/168 reads (19%) | called by muse, mutect2, varscan2
- CFAP47 | c.*50T>C | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- DNAJA4 | chr15:78264270 G>A | 5'Flank (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- GTPBP3 | c.302-12C>A | Intron (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- IGLL1 | c.-55T>C | 5'UTR (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- NMRK1 | c.389+93C>G | Intron (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- RALYL | c.-24+509A>G | Intron (SNP) | VAF 91/176 reads (52%) | called by muse, mutect2, varscan2
- SVIP | c.*2830T>G | 3'UTR (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
